Somatic mutation profile of tumor specimen 0DMZ6G from CCDI case PBCAIP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,874 days).
Specimen 0DMZ6G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e25f47c6-95ad-4323-941e-25ccf51fcfb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMIPI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49293701-f3dd-46a8-81eb-f32a2daad4b1

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Intron 4, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN9A | c.1979C>T p.T660M (on ENST00000303354; = p.T649M on NM_002977.3) | Missense Mutation (SNP) | VAF 134/1240 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs200965749, COSV57620767; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- BRPF1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 194/1516 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1465578133, COSV57403643; called by muse, mutect2, varscan2
- DGCR8 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 378/455 reads (83%) | catalogued as COSV61228888; called by muse, mutect2, varscan2
- OR52B4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 156/1654 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs200795232; called by muse, mutect2
- RASGRP1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 102/989 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.727); catalogued as rs1200829567, COSV60363673; called by muse, mutect2, varscan2
- TUSC3 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 72/2345 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1262917934; called by muse, mutect2
- CCDC85A | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 54/869 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- CFAP47 | c.8900A>T p.E2967V | Missense Mutation (SNP) | VAF 240/2690 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); called by muse, mutect2
- GABRR1 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 225/2014 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GDAP1 | c.377A>C p.E126A | Missense Mutation (SNP) | VAF 932/2179 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GSN | c.2198C>G p.T733R | Missense Mutation (SNP) | VAF 452/1247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 118/2747 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IL16 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 52/1496 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2
- REEP2 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 79/830 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- SLC52A2 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 278/805 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SON | c.6098T>C p.I2033T | Missense Mutation (SNP) | VAF 201/1830 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); called by muse, varscan2
- TMC6 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 82/919 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 84/2814 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- CIZ1 | c.2544C>T p.C848= | Silent (SNP) | VAF 88/1169 reads (8%) | catalogued as rs1004042992, COSV52972478; called by muse, mutect2
- GDF5 | c.1354C>T p.L452= | Silent (SNP) | VAF 55/407 reads (14%) | called by muse, mutect2, varscan2
- GK | c.972G>A p.L324= (on ENST00000427190 / NM_001205019.2; = p.L318= on NM_000167.6) | Silent (SNP) | VAF 128/1732 reads (7%) | catalogued as COSV66739082; called by muse, mutect2
- GRHL1 | c.993T>G p.A331= | Silent (SNP) | VAF 382/1621 reads (24%) | called by muse, mutect2, varscan2
- MAOB | c.414C>A p.P138= | Silent (SNP) | VAF 62/2345 reads (3%) | called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 83/2786 reads (3%) | catalogued as rs1267156464; called by muse, mutect2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 42/1150 reads (4%) | called by muse, mutect2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 11/244 reads (5%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 32/568 reads (6%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 18/223 reads (8%) | called by muse, mutect2, varscan2
- PML | c.1711-17G>C | Intron (SNP) | VAF 22/596 reads (4%) | catalogued as rs1312746052; called by muse, mutect2
